Gene-level copy-number profile of tumor specimen ALCH-AC6G-TTP1-B from ALCHEMIST case ALCH-AC6G, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 46.5 years (16,997 days).
Specimen ALCH-AC6G-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5810b1a9-5adf-42a0-86b4-b887f21f99e4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AC6G-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/0495eb86-e9f6-4936-bed0-6064d15cf3a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 47; copy number 1: 24,201; copy number 2: 32,908; copy number 3: 1,116; copy number 4: 99; copy number 5: 9; copy number 6: 13; copy number 11: 2.

Homozygous deletions (total copy number 0; autosomes only): 45 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,526,318–28,527,227, 1 gene (within-gene range 0–1): PRDX3P2.
- chr3:32,685,145–32,897,824, 5 genes: CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71.
- chr3:109,293,788–109,316,517, 2 genes (within-gene range 0–1): DPPA2, Metazoa_SRP.
- chr7:74,894,116–74,897,835, 2 genes: PMS2P5, Y_RNA.
- chr9:6,639,139–6,727,438, 8 genes (within-gene range 0–1): RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr9:6,734,598–6,748,981, 2 genes (within-gene range 0–1): PRELID3BP11, SNRPEP2.
- chr11:70,862,790–70,872,368, 2 genes (within-gene range 0–2): SHANK2-AS3, MIR3664.
- chr13:19,818,121–19,818,619, 1 gene: ST6GALNAC4P1.
- chr15:20,344,736–20,359,166, 1 gene: AC026495.1.
- chr15:34,489,002–34,495,900, 2 genes: HNRNPLP2, FSCN1P1.
- chr15:34,525,207–34,588,503, 3 genes: GOLGA8B, MIR1233-2, AC027139.1.
- chr15:41,284,007–41,380,996, 1 gene (within-gene range 0–1): AC087721.2.
- chr15:41,320,794–41,409,403, 3 genes (within-gene range 0–1): NUSAP1, AC087721.1, NDUFAF1.
- chr15:41,493,393–41,503,551, 1 gene: ITPKA.
- chr16:89,657,740–89,696,354, 4 genes (within-gene range 0–2): SPATA33, AC010538.1, CDK10, LINC02166.
- chr16:89,737,549–89,816,657, 1 gene (within-gene range 0–1): FANCA.
- chr19:54,107,013–54,115,675, 1 gene (within-gene range 0–1): TFPT.
- chr22:17,980,868–18,007,308, 3 genes (within-gene range 0–1): MIR648, AC016027.3, AC016027.2.
- chr22:18,110,331–18,146,554, 2 genes (within-gene range 0–1): TUBA8, AC008079.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,784,780–180,861,285, 6 genes, copy number 5: MGAT1, AC022413.1, HEIH, LINC00847, AC022413.2, ZFP62.
- chr7:74,796,144–74,851,551, 1 gene, copy number 5: GTF2IRD2.
- chr7:75,395,063–75,416,787, 2 genes, copy number 6 (within-gene range 2–6): TRIM73, NSUN5P1.
- chr22:18,636,445–18,719,341, 3 genes, copy number 5–11: CA15P2, PPP1R26P2, PPP1R26P4.
- chr22:21,167,758–21,192,156, 1 gene, copy number 6 (within-gene range 4–6): FAM230B.
- chr22:21,193,360–21,371,945, 11 genes, copy number 5–6: FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2, PPP1R26P5, LINC01651, AP000552.1.

Autosomal genes at a single copy (total copy number 1): 23,406. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
